CPTAC case C3L-05262 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/63ed186b-32da-4ca2-bd3b-27d7a7b17d1f

Demographics
Sex at birth: male; Race: white; Year of birth: 1965; Vital status: Dead; Days to death: 449 days (1.2 years); Year of death: 2020; Country of birth: Serbia.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin, NOS; Age at diagnosis: 53.7 years (19,625 days); Year of diagnosis: 2019; AJCC staging edition: 8th; AJCC clinical M: M1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IV; Residual disease: RX; Last known disease status: With tumor; Days to last known disease status: 449 days (1.2 years); Progression or recurrence: yes; Days to recurrence: 303 days; Days to last follow up: 345 days; Clark level: IV; Tumor focality: Unifocal; Ulceration indicator: No.
   Pathology details: Breslow thickness category: >2.0-4.0 mm; Greatest tumor dimension: 1.5 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymphatic invasion present: No; Margin status: Indeterminate; Perineural invasion present: No; Vascular invasion present: No.

Follow-up (1 entry)
- Days to follow up: 345 days; Disease response: With Tumor.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 9.8; Cigarettes per day: 5; Tobacco smoking onset year: 1979; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 43.

Biospecimens (5 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-05262-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -11 days; Initial weight: 118 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-05262-22: Section location: Lymph node; Percent tumor nuclei: 80; Percent necrosis: 0.
- Sample C3L-05262-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -11 days; Initial weight: 83 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-05262-25: Section location: Lymph node; Percent tumor nuclei: 80; Percent necrosis: 0.
- Sample C3L-05262-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -11 days; Initial weight: 79 mg; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-05262-08: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -11 days; Initial weight: 105 mg; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-05262-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -12 days; Method of sample procurement: Blood Draw.
